Somatic mutation profile of tumor specimen MMRF_1601_1_BM_CD138pos (aliquot MMRF_1601_1_BM_CD138pos_T2_KBS5U_K11927) from MMRF case MMRF_1601, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.8 years (30,975 days).
Specimen MMRF_1601_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d9eae55-4472-4bb6-bdf1-17519bd675e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1601_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1601_1_PB_Whole_C7_KBS5U_K11897; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e63e6068-ecac-4536-ab05-ff9b668e43ea

The open-access MAF lists 39 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 3'UTR 11, Silent 5, Intron 2, 3'Flank 1, RNA 1, 5'Flank 1, Splice Region 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP23 | c.2753G>A p.R918H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs945638061; called by muse, mutect2
- C16orf89 | c.868+1G>A p.X290_splice | Splice Site (SNP) | VAF 8/122 reads (7%) | catalogued as rs1359023045; called by muse, mutect2
- HIF3A | c.524G>A p.R175H (on ENST00000377670 / NM_152795.4; = p.R106H on NM_022462.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs537314246; called by muse, mutect2, varscan2
- IGF1R | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1223089854, COSV51274565, COSV51309697; called by muse, mutect2
- IGLJ4 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 12/160 reads (8%) | catalogued as rs1227643033; called by muse, mutect2
- NEPRO | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.11); catalogued as rs148625108; called by muse, mutect2
- NPAS2 | c.1274A>G p.E425G | Missense Mutation (SNP) | VAF 5/119 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1360678485; called by muse, mutect2
- YIPF6 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV65856172; called by muse, mutect2
- CALB1 | c.219A>G p.I73M | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2
- CCT8L2 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- MAST1 | c.3131G>T p.G1044V | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTDSS1 | c.1176T>G p.A392= | Splice Region (SNP) | VAF 16/264 reads (6%) | called by muse, mutect2
- RFTN1 | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- SLC22A18 | c.1163A>G p.Y388C | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TRIP12 | c.3044A>T p.Y1015F | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZNF512B | c.1563G>C p.K521N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF808 | c.2036A>G p.Y679C | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP44 | c.2433G>A p.E811= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- CAST | c.1326G>A p.G442= (on ENST00000341926; = p.G525= on NM_001750.7 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV57790935; called by muse, mutect2, varscan2
- LAMA2 | c.5325A>G p.K1775= | Silent (SNP) | VAF 6/143 reads (4%) | catalogued as COSV70348307; called by muse, mutect2
- PCDH15 | c.2583G>T p.V861= | Silent (SNP) | VAF 9/199 reads (5%) | called by muse, mutect2
- PI16 | c.49C>T p.L17= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- AC112695.1 | n.515A>C | RNA (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- APOA1 | c.-21+75T>C | Intron (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- BCOR | c.*433T>G | 3'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- BTBD11 | c.-205G>A | 5'UTR (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
- CIAO2A | c.*282T>C | 3'UTR (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- EIF2AK2 | c.*2947T>C | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- HMGB3 | c.*1900A>C | 3'UTR (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- NFE2L3 | c.*556T>C | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- NLGN1 | c.*3000C>T | 3'UTR (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- PLSCR4 | c.*1341G>A | 3'UTR (SNP) | VAF 10/187 reads (5%) | called by muse, mutect2
- RER1 | chr1:2403459 C>T | 3'Flank (SNP) | VAF 3/46 reads (7%) | catalogued as rs1251906911; called by muse, mutect2
- SLC26A11 | c.*403G>A | 3'UTR (SNP) | VAF 14/163 reads (9%) | called by muse, mutect2
- STARD4 | c.*3215T>G | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- TIMP2 | c.*1117T>C | 3'UTR (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- TMEM52 | c.170+170G>A | Intron (SNP) | VAF 3/33 reads (9%) | catalogued as rs1170521194; called by muse, mutect2
- TSLP | chr5:111071300 T>C | 5'Flank (SNP) | VAF 13/216 reads (6%) | catalogued as rs999831635; called by muse, mutect2
- VPS26A | c.*1221_*1243del | 3'UTR (DEL) | VAF 6/83 reads (7%) | called by mutect2, pindel
